Somatic mutation profile of tumor specimen 0DJGE0 from CCDI case PBBWLE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Middle ear; Age at diagnosis: 6.2 years (2,249 days).
Specimen 0DJGE0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13aafd6d-5678-4b57-a858-c5a146591c3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJG6Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92d4818d-0cbb-4b7f-b081-b55466a79407

The open-access MAF lists 72 somatic variants for this specimen: 51 protein-altering or splice-affecting, 11 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 11, Intron 7, Nonsense Mutation 5, Frame Shift Del 4, 3'UTR 2, Splice Region 1, 5'UTR 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2305G>T p.D769Y | Missense Mutation (SNP) | VAF 96/293 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913468, COSV54062373, COSV54062425, COSV54063143; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ADGRV1 | c.6796G>A p.G2266S | Missense Mutation (SNP) | VAF 297/1317 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs568119384, COSV67979644; called by muse, mutect2, varscan2
- AGTR2 | c.799A>G p.I267V | Missense Mutation (SNP) | VAF 363/520 reads (70%) | SIFT tolerated (0.24); PolyPhen benign (0.124); catalogued as rs1340061634; called by muse, mutect2, varscan2
- ARHGAP30 | c.2460C>A p.S820R | Missense Mutation (SNP) | VAF 165/609 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs149223382; called by muse, mutect2, varscan2
- C1orf109 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 200/607 reads (33%) | catalogued as rs777201466; called by muse, mutect2, varscan2
- CYP2C8 | c.1466C>G p.P489R | Missense Mutation (SNP) | VAF 157/788 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs140481138, COSV100987881; called by muse, mutect2, varscan2
- DCPS | c.230del p.G77Efs*6 | Frame Shift Del (DEL) | VAF 157/522 reads (30%) | catalogued as rs1555072084; called by mutect2, pindel, varscan2
- FRMD3 | c.489C>G p.Y163* | Nonsense Mutation (SNP) | VAF 204/742 reads (27%) | catalogued as COSV58460392; called by muse, mutect2, varscan2
- GCN1 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 131/549 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs766126702, COSV56105470; called by muse, mutect2, varscan2
- GIMAP8 | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 384/1516 reads (25%) | catalogued as rs760973666, COSV56232241; called by muse, mutect2, varscan2
- GOLGA6L6 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.536); catalogued as rs1401507263; called by muse, mutect2
- GRIK5 | c.2519C>T p.S840L | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.523); catalogued as rs1555870401; called by muse, mutect2, varscan2
- GTSF1L | c.395_398del p.K132Sfs*39 | Frame Shift Del (DEL) | VAF 222/729 reads (30%) | catalogued as rs776577520; called by mutect2, pindel, varscan2
- KCNQ3 | c.1564G>A p.V522I | Missense Mutation (SNP) | VAF 114/889 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.298); catalogued as rs143683496; ClinVar: benign / conflicting interpretations of pathogenicity / uncertain significance; called by muse, varscan2
- KLHL34 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 247/328 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs970987750, COSV65279617; called by muse, mutect2, varscan2
- LUC7L | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 130/388 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.381); catalogued as rs1246595858; called by muse, mutect2, varscan2
- MAGEL2 | c.2246G>A p.R749H | Missense Mutation (SNP) | VAF 183/554 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV100046254; called by muse, mutect2, varscan2
- MGAM2 | c.916T>C p.F306L | Missense Mutation (SNP) | VAF 343/1542 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as COSV101522884; called by muse, mutect2, varscan2
- NF1 | c.3974G>T p.R1325M | Missense Mutation (SNP) | VAF 312/908 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs863224447, CM153417, CS072251, COSV62225257; ClinVar: uncertain significance; called by mutect2, varscan2
- TDRD3 | c.1937C>A p.P646Q | Missense Mutation (SNP) | VAF 235/688 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52165550; called by muse, mutect2, varscan2
- TNFRSF11B | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 299/2790 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs145544246; called by muse, mutect2, varscan2
- USP7 | c.454C>G p.R152G | Missense Mutation (SNP) | VAF 42/715 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV61215377; called by muse, mutect2
- VPS4B | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 189/684 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs910450361; called by muse, mutect2, varscan2
- ZNF282 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 178/686 reads (26%) | catalogued as COSV50483361; called by muse, mutect2, varscan2
- ARRB1 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 87/364 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- BCOR | c.1629_1644del p.C544Afs*40 | Frame Shift Del (DEL) | VAF 170/235 reads (72%) | called by mutect2, pindel, varscan2
- CLCN1 | c.979+2T>C p.X327_splice | Splice Site (SNP) | VAF 253/1082 reads (23%) | called by muse, mutect2, varscan2
- COL14A1 | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 347/2290 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- DISP2 | c.1258T>A p.F420I | Missense Mutation (SNP) | VAF 94/325 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ECE2 | c.2164-6C>T | Splice Region (SNP) | VAF 69/201 reads (34%) | called by muse, mutect2, varscan2
- ERICH6B | c.28G>T p.G10* | Nonsense Mutation (SNP) | VAF 183/552 reads (33%) | called by muse, mutect2, varscan2
- FHOD3 | c.736_742del p.N246Wfs*19 | Frame Shift Del (DEL) | VAF 196/733 reads (27%) | called by mutect2, pindel, varscan2
- IGF2R | c.2433T>G p.I811M | Missense Mutation (SNP) | VAF 191/620 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- KCNJ9 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 99/361 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- MUC19 | c.208T>C p.C70R | Missense Mutation (SNP) | VAF 128/731 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH7B | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 216/664 reads (33%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYO7A | c.3614_3617delinsT p.S1205_E1206delinsL | In Frame Del (DEL) | VAF 125/540 reads (23%) | called by pindel, varscan2*
- MYOM1 | c.637C>A p.Q213K | Missense Mutation (SNP) | VAF 412/1104 reads (37%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.345); called by mutect2, varscan2
- NUDT5 | c.447C>A p.N149K | Missense Mutation (SNP) | VAF 283/847 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIGX | c.496G>T p.V166F | Missense Mutation (SNP) | VAF 220/908 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by mutect2, varscan2
- PROM2 | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 110/544 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PTPRO | c.3116G>C p.C1039S (on ENST00000281171 / NM_030667.3; = p.C1011S on NM_002848.4) | Missense Mutation (SNP) | VAF 359/1383 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RNF17 | c.2947C>A p.Q983K | Missense Mutation (SNP) | VAF 227/718 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- SGSM3 | c.54C>A p.S18R | Missense Mutation (SNP) | VAF 227/710 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- SPINK5 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 211/994 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- STOML3 | c.347A>T p.D116V | Missense Mutation (SNP) | VAF 294/864 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAP1 | c.1496A>G p.Y499C | Missense Mutation (SNP) | VAF 84/253 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VCP | c.1231T>G p.L411V | Missense Mutation (SNP) | VAF 190/591 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF608 | c.2239C>T p.P747S | Missense Mutation (SNP) | VAF 277/748 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- ZNF665 | c.1488G>T p.Q496H (on ENST00000600412; = p.Q561H on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- ZSCAN20 | c.264G>T p.E88D | Missense Mutation (SNP) | VAF 190/544 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- DLL4 | c.1032T>C p.D344= | Silent (SNP) | VAF 124/350 reads (35%) | called by muse, mutect2, varscan2
- DNAAF4 | c.1179T>G p.L393= | Silent (SNP) | VAF 196/588 reads (33%) | called by muse, mutect2, varscan2
- DNAH7 | c.2787T>C p.I929= | Silent (SNP) | VAF 288/1298 reads (22%) | called by muse, mutect2, varscan2
- FREM3 | c.2259C>G p.G753= | Silent (SNP) | VAF 235/827 reads (28%) | called by muse, mutect2, varscan2
- HTT | c.4161C>T p.T1387= | Silent (SNP) | VAF 255/761 reads (34%) | catalogued as rs1475429505, COSV100751301; called by muse, mutect2, varscan2
- LTA4H | c.1191G>T p.L397= | Silent (SNP) | VAF 300/1326 reads (23%) | called by mutect2, varscan2
- MACF1 | c.3594G>A p.S1198= | Silent (SNP) | VAF 293/898 reads (33%) | catalogued as rs777900207; called by muse, mutect2, varscan2
- PTPRT | c.2376T>C p.S792= | Silent (SNP) | VAF 259/732 reads (35%) | called by muse, mutect2, varscan2
- SOS2 | c.804T>C p.T268= | Silent (SNP) | VAF 42/899 reads (5%) | catalogued as rs750437794; ClinVar: likely benign; called by muse, mutect2
- TKT | c.198G>A p.P66= | Silent (SNP) | VAF 83/387 reads (21%) | catalogued as COSV56244301; called by muse, mutect2, varscan2
- TRAIP | c.996C>G p.S332= | Silent (SNP) | VAF 208/646 reads (32%) | catalogued as COSV58913165; called by muse, mutect2, varscan2
- ATG3 | c.863+30C>A | Intron (SNP) | VAF 222/768 reads (29%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-2408G>T | Intron (SNP) | VAF 86/300 reads (29%) | called by muse, varscan2
- KIF5C | c.2374-79G>T | Intron (SNP) | VAF 7/144 reads (5%) | called by muse, mutect2
- MYBPC1 | c.62-9T>C | Intron (SNP) | VAF 291/1237 reads (24%) | called by muse, mutect2, varscan2
- NRP2 | c.2440+9441G>C | Intron (SNP) | VAF 101/478 reads (21%) | catalogued as rs750921394; called by muse, mutect2, varscan2
- PRSS27 | c.678+99C>G | Intron (SNP) | VAF 28/73 reads (38%) | called by muse, mutect2, varscan2
- RFPL4B | c.-66G>T | 5'UTR (SNP) | VAF 48/142 reads (34%) | catalogued as rs1415201026; called by muse, mutect2, varscan2
- SAP25 | c.218-37G>T | Intron (SNP) | VAF 92/319 reads (29%) | called by muse, mutect2, varscan2
- TNFRSF10C | c.*52C>T | 3'UTR (SNP) | VAF 136/840 reads (16%) | catalogued as rs756963326, COSV100790525; called by muse, mutect2, varscan2
- TRIM8 | c.*309G>A | 3'UTR (SNP) | VAF 158/464 reads (34%) | called by muse, mutect2, varscan2
